Surgical pathology report (de-identified scan), TCGA case TCGA-FP-8099, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-FP-8099-01A (Primary Tumor).

[page 1 of 3]
Surg Path Final Report

* Final Report *

* Final Report *

SURG PATH FINAL REPORT

SURGICAL PATHOLOGY

Collected:
Accession:
Physician:

PROCEDURE

Esophagogastroduodenoscopy.

SPECIMEN:

- A. Esophageal margin at suture line - esophagus (initial surgical margin).
- B. Esophagus true margin at staple line.
- C. Gastric esophageal junction.

HISTORY

Esophageal cancer. A -year-old with esophageal adenocarcinoma.

GROSS

A. Labeled "esophagus check suture line check margins," is a 2.7 x 1.5 x 1.2 cm short segment of tube, closed by staple line at both ends. One end is labeled with a stitch of black suture, indicated by the surgeon to be the margin to examine by frozen section. This margin is submitted en toto for frozen section examination. Mucosa is tan-white and free of tumor mass. Opposite stapled margin block 2. Multiple/4

B. Labeled "esophagus true margin at staple" is a 2.5 x 1.7 x 1.5 cm tubular segment of pink-tan tissue with tan-white mucosa, free of gross lesion. The stapled edge is inked black. Representative longitudinal sections are submitted in two cassettes.

C. Received in formalin in a container labeled "gastroesophageal junction" is a portion of distal esophagus and proximal stomach representing the gastroesophageal junction (9 x 8 x 3.2 cm). The distal esophagus (3 cm long, 3.5 cm in circumference) has a 0.8 cm in greatest dimension ulcer at the gastroesophageal junction, measuring 2.1 cm from the proximal margin and 3.8 cm from the distal margin. The underlying muscularis propria is focally up to 1 cm, thick. Invasive tumor is not grossly apparent. The gastric mucosa has prominent rugae and is otherwise unremarkable. The adipose tissue has multiple firm tan lymph nodes up to 0.6 cm in greatest dimension.

Ink Code:

Printed by:
Printed on:

Page 1 of 3
(Continued)

[page 2 of 3]
Surg Path Final Report

* Final Report *

Green - proximal.
Purple - distal.
Black - adventitia margin.

1. Representative sections of the adventitia margin overlying the gastroesophageal junction ulcer. [REDACTED]
- 2-7. Full thickness sections through the gastroesophageal junction ulcer. 6NS
8. Perpendicular sections adjacent to the stapled distal resection margin. 2SS
- 9-10. Small lymph nodes. 15NS
- 11-13. Bisected lymph nodes (one lymph node per cassette). 6NS
- [REDACTED]

FROZEN SECTION DIAGNOSIS

- A. Esophagus, initial surgical margin, resection: Smooth muscle wall, free of tumor. No mucosa sampled. TCP (Diagnosis to [REDACTED])

INTRAOPERATIVE CONSULTATION

- B. Esophagus, true margin at staple, resection: No gross evidence of tumor. TCP (Diagnosis to [REDACTED])

- C. Gastroesophageal junction, resection: Distal resection margin, grossly free of lesion. Tumor 7.4 cm proximal to distal margin. TCP (Diagnosis to Dr [REDACTED])

MICROSCOPIC

Performed.

DIAGNOSIS

- A. Esophagus, initial surgical margin, resection:
Segment of esophagus with benign squamous mucosa and smooth muscle. No tumor seen. [REDACTED]
- B. Esophagus, true margin, resection:
Segment of esophagus with benign squamous mucosa and smooth muscle. No tumor seen. [REDACTED]
- C. Gastroesophageal junction, resection:
Invasive adenocarcinoma (2.2 cm in greatest dimension), moderately differentiated extending to adventitia. Tumor arising from gastroesophageal junction. Perineural invasion is present. Lymphovascular invasion is not seen. Distal gastric margin and circumferential adventitia margins are negative for tumor. Extensive Barrett's esophagitis. Thirteen (13) lymph nodes are negative for tumor (0/13).

Printed by:
Printed on:

Page 2 of 3
(Continued)

[page 3 of 3]
Surg Path Final Report

* Final Report *

COMMENT

ESOPHAGEAL CARCINOMA SUMMARY:

SPECIMEN: Distal esophagus and proximal stomach.

PROCEDURE: Esophagogastrectomy.

TUMOR SITE: Gastroesophageal junction.

TUMOR SIZE: 2.2 cm in greatest dimension.

HISTOLOGIC TYPE: Adenocarcinoma.

HISTOLOGIC GRADE: Moderately differentiated.

MICROSCOPIC TUMOR EXTENSION: Tumor invades through muscularis propria into the adventitia.

MARGIN: Proximal esophageal margin: uninvolved by invasive carcinoma; uninvolved by dysplasia or intestinal metaplasia.

Distal margin: uninvolved by invasive carcinoma; uninvolved by dysplasia.

Circumferential (adventitial) margin: uninvolved by invasive carcinoma.

LYMPHOVASCULAR INVASION: Not identified.

PERINEURAL INVASION: Present.

LYMPH NODES: Negative for tumor (0/13).

PATHOLOGIC STAGING: pT3 N0 MX.

reviewed the case and concurs with the diagnosis.

Completed Action List:

* Order by

Type:

Surg Path Final Report

Date:

Status:

Title:

Encounter info:

Printed by:

Printed on:

Source: NCI Genomic Data Commons file 566df6c1-2bf9-4aa2-9746-fedfd2e73012 (TCGA-FP-8099.797B88F4-68E9-407B-BA30-FEF487F69E31.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).